Surgical pathology report (de-identified scan), TCGA case TCGA-HI-7171, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Fox Chase, specimen TCGA-HI-7171-01A (Primary Tumor).

[page 1 of 2]
Sex: M

CGA - HI - 7171

Source of Specimen(s):

- 1: Left pelvic Lymph Node
- 2: Right pelvic Lymph Node
- 3: Prostate and Seminal Vessicles

Gross Description:

Received in three parts.

Source of tissue: 1. Labeled #1, "left pelvic lymph nodes"

Gross Description: Received fresh labeled ", left pelvic lymph nodes" consists of a 6 x 3 x 1.5 cm aggregate of yellow lobulated, hemorrhagic fat. Multiple lymph nodes are dissected out of the fat ranging from 2 x 2 x 0.4 cm up to 3.5 x 1.5 x 0.4 cm. The lymph nodes are entirely submitted in cassettes 1A-1C for microscopic evaluation.

Source of tissue: 2. Labeled #2, "right pelvic lymph nodes"

Gross Description: Received fresh labeled ", right pelvic lymph nodes" consists of a 4 x 3 x 1 cm aggregate of yellow lobulated, hemorrhagic fat. Two lymph nodes are dissected out of the fat measuring 1 x 1 x 0.3 cm and 2.5 x 1 x 0.4 cm. The lymph nodes are entirely submitted in cassettes 2A for microscopic evaluation.

Source of tissue: 3. Labeled #3, "prostate and seminal vesicles"

Gross Description: Received fresh labeled ", prostate and seminal vesicles" consists of a 58 gram, 5 x 4.5 x 4 cm red-brown, hemorrhagic prostate with intact capsule, patent urethra and bilateral seminal vesicles and vas deferens. The right seminal vesicle measures 2 x 1 x 0.7 cm, the right vas deferens measures 4 x 0.5 cm, the left seminal vesicle measures 4 x 2 x 1 cm, and the left vas deferens measures 5 x 0.5 cm. The right side is inked yellow and the left side is inked black and the specimen is sectioned revealing tan-pink, rubbery to firm cut surfaces with multiple brown, small to medium calculi. Sectioning of the seminal vesicles and vas deferens reveals tan-red cut surfaces and fluid-filled spaces. Representative sections are submitted as designated for microscopic evaluation.

Designation of Sections: 3A right apex. 3B left apex. 3C right base. 3D left base. 3E-3F right anterior mid. 3G-3H right posterior superior. 3I-3J left anterior mid. 3K-3L left posterior superior. 3M right seminal vesicle and vas deferens. 3N left seminal vesicle and vasdeferens. Please note the specimens are placed in formalin at

Final Diagnosis:

1. Left pelvic lymph nodes:
- No tumor seen in five lymph nodes (0/5).

[page 2 of 2]
2. Right pelvic lymph nodes:

- No tumor seen in two lymph nodes (0/2).

3. Prostate and seminal vesicles, radical prostatectomy:

- Prostatic adenocarcinoma, Gleason's score 9 (5+4).
- Tumor involves both lobes.
- Tumor involves the apex on the right side, extending into the surrounding muscles and nerves, but the inked margin is negative.
- Angiolymphatic invasion is not identified.
- Perineural invasion is identified.
- Extracapsular extension is identified.
- Tumor involves right posterior inked margin.
- Left and right seminal vesicles positive for tumor.
- Tumor involves 80% of tissue examined.
- pT3b N0 Mx

Source: NCI Genomic Data Commons file 6bd86747-e2f3-4260-92b6-1aeeaff465f6 (TCGA-HI-7171.0BDD67BB-5CF4-4972-9AB6-9878C351857F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).